Somatic mutation profile of tumor specimen TARGET-40-PANXSC-01A (aliquot TARGET-40-PANXSC-01A-01D) from TARGET case TARGET-40-PANXSC, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.2 years (5,545 days).
Specimen TARGET-40-PANXSC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fada1149-7bc5-477c-aef5-28bf73b33322.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANXSC-10A (Blood Derived Normal), aliquot TARGET-40-PANXSC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc9e8bde-fe8b-4042-abdf-f93905957c16

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, 5'UTR 2, Splice Region 2, RNA 1, Nonsense Mutation 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAF2 | c.930G>C p.K310N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV56131022; called by muse, mutect2, varscan2
- HMX3 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs750180442, COSV63501529; called by muse, mutect2, varscan2
- SLC28A1 | c.1369G>C p.G457R | Missense Mutation (SNP) | VAF 117/1102 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.71); catalogued as COSV99723207; called by muse, mutect2, varscan2
- AURKA | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 61/551 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRC6A | c.215T>A p.L72H | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MZF1 | c.1805G>A p.C602Y | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- NEURL4 | c.316del p.V106* | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- NNT | c.2874C>T p.V958= | Splice Region (SNP) | VAF 29/356 reads (8%) | called by muse, mutect2
- NOL11 | c.1404-6_1404-3del | Splice Region (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- OR2B3 | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB5A | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- RND3 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RNF139 | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 70/470 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.226); called by muse, mutect2
- SCN8A | c.3547T>A p.S1183T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SULT1C3 | c.80C>G p.P27R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- ZNF142 | c.2855C>T p.A952V (on ENST00000411696 / NM_001379660.1; = p.A752V on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF682 | c.1106A>G p.Y369C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1941C>T p.H647= | Silent (SNP) | VAF 145/201 reads (72%) | catalogued as rs757585535; called by muse, mutect2, varscan2
- PNCK | c.639C>T p.Y213= (on ENST00000340888 / NM_001366975.1; = p.Y296= on NM_001039582.3) | Silent (SNP) | VAF 107/160 reads (67%) | catalogued as rs782094866, COSV61742505; called by muse, mutect2, varscan2
- PSMA1 | c.441C>A p.T147= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- RAB2B | c.30C>T p.I10= | Silent (SNP) | VAF 26/179 reads (15%) | catalogued as COSV52967675; called by muse, mutect2, varscan2
- COG7 | c.2146+78G>T | Intron (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2
- GRK4 | c.-97C>T | 5'UTR (SNP) | VAF 6/24 reads (25%) | catalogued as rs750312486; called by muse, mutect2
- TUBB8P11 | n.89G>A | RNA (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- XKR3 | c.-6C>A | 5'UTR (SNP) | VAF 21/162 reads (13%) | called by muse, mutect2, varscan2
